CCDI case PBCJVC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/85cb6aa4-53b3-4d20-bc49-6e79d72cf053

Demographics
Sex at birth: female; Race: american indian or alaska native.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,675 days).

Biospecimens (3 samples)
- Sample 0DTNVI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTNWI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTNXA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
